Gene-level copy-number profile of tumor specimen TARGET-40-PASUUH-01A from TARGET case TARGET-40-PASUUH, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.1 years (5,143 days).
Specimen TARGET-40-PASUUH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.cf949c11-8afe-53c1-a0f9-9b6127f57cda.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASUUH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 437 have no estimate.
https://portal.gdc.cancer.gov/files/7c26c346-92b0-43ca-80d9-aff0e8e7e1ed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,261; copy number 1: 3,112; copy number 2: 13,824; copy number 3: 11,599; copy number 4: 22,211; copy number 5: 3,050; copy number 6: 1,510; copy number 7: 1,528; copy number 8: 340; copy number 9: 248; copy number 10: 194; copy number 11: 59; copy number 12: 104; copy number 13: 159; copy number 14: 159; copy number 15: 240; copy number 16: 107; copy number 17: 62; copy number 18: 254; copy number 19: 2; copy number 20: 11; copy number 22: 46; copy number 29: 24; copy number 42: 8; copy number 45: 74.

Homozygous deletions (total copy number 0; autosomes only): 741 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:94,506,766–94,507,620, 1 gene: ARMC10P1.
- chr3:95,654,423–96,777,683, 11 genes: MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1.
- chr3:96,814,581–97,752,460, 2 genes: EPHA6, AC117470.1.
- chr3:110,682,286–111,665,750, 7 genes (within-gene range 0–2): RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2.
- chr3:114,276,913–115,564,389, 15 genes (within-gene range 0–1): TIGIT, ZBTB20, AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5, ZBTB20-AS2, MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3.
- chr3:116,709,235–117,027,039, 7 genes: TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr6:87,826,173–117,273,565, 377 genes (broad region; genes not listed).
- chr6:117,299,364–117,301,758, 2 genes: RN7SKP18, RN7SKP51.
- chr6:117,907,264–118,317,676, 1 gene (within-gene range 0–2): SLC35F1.
- chr6:118,452,469–126,258,355, 78 genes (broad region; genes not listed).
- chr6:126,340,115–126,484,713, 2 genes: CENPW, MIR588.
- chr7:142,252,143–146,050,366, 183 genes (within-gene range 0–3) (broad region; genes not listed).
- chr7:146,208,665–146,311,822, 2 genes: AC073418.1, Y_RNA.
- chr16:72,973,374–73,099,337, 6 genes: AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1, HCCAT5.
- chr17:14,834,557–15,417,878, 17 genes: LINC02096, RPL23AP76, AC005772.1, CDRT7, AC005772.2, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P.
- chr17:15,436,021–15,563,595, 3 genes (within-gene range 0–10): TVP23C-CDRT4, RPL9P2, TVP23C.
- chr17:15,530,773–15,999,717, 27 genes: AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,751 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 4–12): AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr8:78,605,952–80,080,775, 21 genes, copy number 9–15 (within-gene range 4–15): AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2.
- chr8:84,182,787–135,742,495, 742 genes, copy number 9–20 (within-gene range 6–20) (broad region; genes not listed).
- chr8:135,977,329–136,295,232, 2 genes, copy number 9 (within-gene range 6–9): AC103955.1, AC023781.1.
- chr13:60,618,991–61,176,758, 1 gene, copy number 13 (within-gene range 6–13): LINC00378.
- chr13:60,730,176–60,945,955, 3 genes, copy number 13: AL161901.1, RNY3P5, LINC01442.
- chr13:62,212,577–63,097,797, 9 genes, copy number 9: LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1.
- chr13:91,023,732–93,227,317, 27 genes, copy number 11–15: BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1.
- chr13:93,309,669–93,311,063, 1 gene, copy number 15: AL160159.1.
- chr13:94,154,193–96,839,562, 33 genes, copy number 9–15 (within-gene range 4–15): GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1.
- chr13:97,901,653–107,933,503, 141 genes, copy number 10–17 (within-gene range 4–17) (broad region; genes not listed).
- chr14:105,881,034–105,972,269, 31 genes, copy number 16: IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6.
- chr15:90,074,512–90,502,239, 26 genes, copy number 10 (within-gene range 7–10): ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr17:7,705,202–11,969,748, 126 genes, copy number 10–19 (within-gene range 8–19) (broad region; genes not listed).
- chr17:12,549,764–14,236,862, 23 genes, copy number 9–20: LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093, HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15.
- chr17:14,705,076–14,780,686, 3 genes, copy number 13: RPS18P12, AC013248.1, AC005863.1.
- chr17:15,436,015–15,503,608, 1 gene, copy number 10 (within-gene range 0–10): CDRT4.
- chr17:15,506,866–15,507,354, 1 gene, copy number 10: PPIAP53.
- chr17:15,999,784–21,260,501, 298 genes, copy number 9–22 (within-gene range 0–22) (broad region; genes not listed).
- chr17:69,961,568–73,092,712, 33 genes, copy number 9 (within-gene range 8–9): LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.
- chr19:27,638,483–35,124,324, 187 genes, copy number 15–45 (within-gene range 15–110) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
